Somatic mutation profile of tumor specimen C3N-01764-01 (aliquot CPT0181320006) from CPTAC case C3N-01764, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.6 years (26,880 days).
Specimen C3N-01764-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3061a15-1843-4a4c-9c70-ea3975142459.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01764-31 (Blood Derived Normal), aliquot CPT0181420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/653bf8f5-796c-4ee3-8883-ad2f3edc908f

The open-access MAF lists 78 somatic variants for this specimen: 56 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 14, Intron 4, Frame Shift Del 2, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, Splice Site 1, RNA 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 51/117 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 65/168 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 110/284 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APRT | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 32/215 reads (15%) | catalogued as rs369681854, CM102691; called by muse, mutect2, varscan2
- ARMC7 | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99822603; called by muse, mutect2, varscan2
- ATP1A2 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1282248061, CM105895, COSV63405089; ClinVar: uncertain significance; called by muse, mutect2
- AWAT1 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65739126; called by muse, mutect2, varscan2
- CDH7 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as rs749777659, COSV59889883; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2
- CNOT1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.115); catalogued as rs1273997659; called by muse, mutect2, varscan2
- COL4A6 | c.4763C>T p.P1588L | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371347527; called by muse, mutect2, varscan2
- CXorf66 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as COSV65169267; called by muse, mutect2, varscan2
- FKBP3 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1315616175; called by muse, mutect2, varscan2
- FYB1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as COSV100686610; called by muse, mutect2
- GAB1 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53757645; called by muse, mutect2, varscan2
- GSE1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV99495871; called by muse, mutect2, varscan2
- KLHDC7A | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 125/418 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV101272744; called by muse, mutect2, varscan2
- MGAT4C | c.343T>A p.Y115N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1195235271; called by muse, mutect2, varscan2
- MYO18B | c.7148G>C p.R2383P | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV59129934; called by muse, mutect2, varscan2
- PHLPP1 | c.5140G>A p.D1714N | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs1440495117; called by muse, mutect2, varscan2
- SH3GL3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs746667690, COSV61056344; called by muse, mutect2, varscan2
- SYN3 | c.1498T>C p.S500P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs769626382; called by muse, mutect2, varscan2
- WDFY3 | c.10026G>T p.E3342D | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV99884742; called by muse, mutect2
- ZNF341 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs762977186; called by muse, mutect2, varscan2
- AATK | c.4082G>A p.R1361K (on ENST00000326724 / NM_001080395.3; = p.R1258K on NM_004920.2) | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMN | c.1182C>G p.H394Q | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2
- CNKSR2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DCST2 | c.1518G>A p.M506I | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DIDO1 | c.6532A>G p.N2178D | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2
- FBXO31 | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GPR39 | c.363_373del p.T122Rfs*7 | Frame Shift Del (DEL) | VAF 32/355 reads (9%) | called by mutect2, pindel
- KIRREL1 | c.1800C>T p.D600= | Splice Region (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2
- KMT2E | c.5405G>A p.S1802N | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- MCM10 | c.2587A>G p.R863G (on ENST00000484800 / NM_182751.3; = p.R862G on NM_018518.5) | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDN1 | c.13711G>T p.V4571L | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.314); called by muse, mutect2
- MED14 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- MYH10 | c.1524C>G p.F508L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NAA25 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCOA1 | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NPAP1 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OR5H2 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PALB2 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- PAX1 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLCL1 | c.3181T>A p.S1061T | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.083); called by muse, mutect2
- PPFIA2 | c.1624C>G p.P542A | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2
- PRR32 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 73/368 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RBM27 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 79/300 reads (26%) | called by muse, mutect2, varscan2
- ROPN1B | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- SCNN1B | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 132/550 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMARCA1 | c.2031del p.F677Lfs*8 | Frame Shift Del (DEL) | VAF 44/180 reads (24%) | called by mutect2, pindel, varscan2
- SMC3 | c.1009dup p.I337Nfs*28 | Frame Shift Ins (INS) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- SPATA22 | c.856A>G p.M286V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- STAT1 | c.373-1G>A p.X125_splice | Splice Site (SNP) | VAF 87/310 reads (28%) | called by muse, mutect2, varscan2
- TANC2 | c.5884A>C p.N1962H | Missense Mutation (SNP) | VAF 161/319 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP40 | c.3314G>A p.R1105K | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF43 | c.1940A>T p.E647V | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ARHGEF3 | c.1077G>A p.V359= | Silent (SNP) | VAF 132/625 reads (21%) | catalogued as rs1031104339; called by muse, mutect2, varscan2
- BSX | c.348T>G p.V116= | Silent (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- CTNNA1 | c.78G>A p.E26= | Silent (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- DENND4A | c.3117G>A p.L1039= | Silent (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- FASN | c.2556C>T p.N852= | Silent (SNP) | VAF 98/153 reads (64%) | catalogued as rs765134185; called by muse, mutect2, varscan2
- LYPD6B | c.66C>T p.L22= (on ENST00000409029 / NM_001317004.1; = p.L46= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- PIGS | c.27A>G p.T9= | Silent (SNP) | VAF 67/221 reads (30%) | catalogued as rs781718371; called by muse, mutect2, varscan2
- PSMA3 | c.561C>T p.C187= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- SDHA | c.954C>T p.L318= | Silent (SNP) | VAF 158/731 reads (22%) | catalogued as rs1412623947; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHFL | c.612C>G p.S204= | Silent (SNP) | VAF 58/564 reads (10%) | catalogued as rs1382917606; called by muse, mutect2
- SLC30A3 | c.648G>A p.P216= | Silent (SNP) | VAF 131/448 reads (29%) | catalogued as rs763440726, COSV99273528; called by muse, mutect2, varscan2
- SOX17 | c.399C>T p.P133= | Silent (SNP) | VAF 134/292 reads (46%) | called by muse, mutect2, varscan2
- TMEM255A | c.375T>A p.A125= | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- TRPC4 | c.2466C>T p.A822= (on ENST00000379705 / NM_016179.4; = p.A827= on NM_003306.3) | Silent (SNP) | VAF 72/146 reads (49%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29702184 G>A | 3'Flank (SNP) | VAF 89/496 reads (18%) | catalogued as rs754990479; called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25498G>A | Intron (SNP) | VAF 64/568 reads (11%) | catalogued as rs527709007; called by muse, varscan2
- EYA1 | c.273-27C>A | Intron (SNP) | VAF 28/389 reads (7%) | called by muse, mutect2
- PAPOLA | c.-14C>G | 5'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- PPM1N | c.939+42C>A | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- SAR1B | c.-11C>T | 5'UTR (SNP) | VAF 56/267 reads (21%) | called by muse, mutect2, varscan2
- SHFL | c.644-23C>G | Intron (SNP) | VAF 54/606 reads (9%) | called by muse, mutect2
- SSPOP | n.10673C>T | RNA (SNP) | VAF 74/241 reads (31%) | called by muse, mutect2, varscan2
